Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29H, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29H-06A (Metastatic).

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Refers to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

yo female with melanoma 1mm Clarke II TMR 1/mm² excised from left shoulder
14/10/10- large solid mass left axilla and FNA showed metastatic melanoma.
CT (staging)-> T2 LN in left axilla suspicious for melanoma. Having left axillary clearance.
B/g obesity, sleep apnoea, type 2DM, HTN. Specimen: left axillary contents.

Axillary U/S

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"LEFT AXILLARY CONTENTS". The specimen consists of fibrofatty muscular tissue.
The specimen measures 200 x 160 x 58mm. There is attached muscle measuring up to
75 x 53 x 25mm. There is one marked area which has been sampled for tumour banking.
This is the largest lymph node measuring 65 x 33 x 33mm. The cut surface appears pathological
with pale and brownish areas. Representative sections of this lesion embedded in blocks A - H.

- A-F. Largest lymph node (sampled for tumour banking).
- G. Two lymph nodes.
- H. Two lymph nodes.
- I. Two lymph nodes.
- K-L. One bisected lymph node.
- M. ?Two lymph nodes.
- N. ?Four lymph nodes.
- P. ?Four lymph nodes.
- Q. One lymph node.
- R. One lymph node.
- S. One bisected fatty lymph nodes.
- T. Two lymph nodes, fatty.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axilla C77.3

hw
6/2/11

Primary Tumour Site Discrepancy		X

MICROSCOPIC REPORT

"LEFT AXILLARY CONTENTS".

Metastatic melanoma is present in 1 of 20 lymph nodes. The metastasis (A-F) is about 65mm across
replacing a lymph node. There is no definite extranodal extension. The tumour consists of epithelioid cells,
many containing fine cytoplasmic pigment and there is extensive tumour necrosis. The remaining 19 lymph
nodes show occasional pigment laden macrophages in sinusoids.

SUMMARY

LEFT AXILLARY LYMPH NODE DISSECTION - METASTATIC MELANOMA IN 1 OF 20 NODES.

REPORTED BY A/Prof.

Printer:

This

Source: NCI Genomic Data Commons file 2b6d239f-ce9d-46b0-808a-9ddcc319bcbd (TCGA-EE-A29H.F04F8CC7-26F1-4916-8FA2-6790E023047E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).